Somatic mutation profile of tumor specimen TCGA-2J-AABT-01A (aliquot TCGA-2J-AABT-01A-11D-A40W-08) from TCGA case TCGA-2J-AABT, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 72.2 years (26,379 days).
Specimen TCGA-2J-AABT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e49d267-e9d6-4979-a173-eeb6b17f550c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABT-10A (Blood Derived Normal), aliquot TCGA-2J-AABT-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb014a72-43eb-4683-8107-4c3efb074d4c

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 26/226 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 27/178 reads (15%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AKAP6 | c.5222C>T p.S1741F | Missense Mutation (SNP) | VAF 59/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99801636; called by muse, mutect2, varscan2
- DNAI4 | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV64031218; called by muse, mutect2
- FOXS1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370481154; called by muse, mutect2, varscan2
- HECW2 | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 69/650 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV99647513; called by muse, mutect2, varscan2
- ITPR3 | c.2749A>G p.I917V | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.323); catalogued as rs754127262, COSV100967511; called by muse, mutect2, varscan2
- KCNK2 | c.1058A>C p.D353A (on ENST00000444842 / NM_001017425.3; = p.D338A on NM_014217.4) | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101222206; called by muse, mutect2, varscan2
- LTA4H | c.778T>G p.L260V | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99957131; called by muse, mutect2, varscan2
- LYSMD3 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 60/494 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs781190639, COSV60057703; called by muse, mutect2, varscan2
- NLRP9 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 56/554 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100243137; called by muse, mutect2, varscan2
- RPP14 | c.197A>C p.Y66S | Missense Mutation (SNP) | VAF 73/549 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99916710; called by muse, mutect2, varscan2
- SLC43A2 | c.1079-1G>A p.X360_splice | Splice Site (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100025028, COSV56772302; called by muse, mutect2
- SNAPC2 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 68/664 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs1051311397, COSV99564126; called by muse, mutect2
- TMEM132E | c.646G>A p.G216R (on ENST00000321639; = p.G306R on NM_001304438.2) | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as rs1390727052, COSV100396453; called by muse, mutect2, varscan2
- TTN | c.5741C>T p.A1914V (on ENST00000591111; = p.A1868V on NM_003319.4) | Missense Mutation (SNP) | VAF 125/836 reads (15%) | PolyPhen probably damaging (0.997); catalogued as rs374203813, COSV59931101; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- USP25 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 32/211 reads (15%) | catalogued as COSV99583961; called by muse, mutect2, varscan2
- ARHGAP10 | c.2143del p.S715Lfs*6 | Frame Shift Del (DEL) | VAF 28/201 reads (14%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1304_1305dup p.S436Lfs*63 (on ENST00000281708 / NM_001349798.2; = p.S356Lfs*63 on NM_018315.5) | Frame Shift Ins (INS) | VAF 91/717 reads (13%) | called by mutect2, pindel, varscan2
- FCAR | c.194dup p.N65Kfs*16 | Frame Shift Ins (INS) | VAF 30/278 reads (11%) | called by mutect2, pindel
- PLEC | c.12291C>T p.P4097= (on ENST00000322810 / NM_201380.4; = p.P3987= on NM_000445.5) | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs899352692, COSV100515359; called by muse, mutect2, varscan2
- RIMBP2 | c.1503C>T p.P501= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs144010117; called by muse, mutect2, varscan2
- RNF213 | c.9360C>T p.Y3120= | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as rs142096377; called by muse, mutect2, varscan2
- TUBGCP2 | c.1176G>A p.E392= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as rs1564940388, COSV99427891; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2700G>A | Intron (SNP) | VAF 44/570 reads (8%) | catalogued as rs768178267, COSV56010933; called by muse, mutect2
